TARGET case TARGET-10-PAPKNJ — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5d424e0-9715-4421-bf49-eda4be25d127

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 4.3 years (1,577 days); Year of diagnosis: 2006; Days to last follow up: 3,476 days (9.5 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (1 entry)
- Days to follow up: 3,476 days (9.5 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,476; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 16.8 ×10³/µL.
- Day 8: Bone Marrow blast count 3%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Samples TARGET-10-PAPKNJ-09A, TARGET-10-PAPKNJ-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPKNJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3476
- WBC at Diagnosis: 16.8
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 3
- BMA Blasts Day 29: 0
- Karyotype: 47,XX,+X,i(X)(p10),dic(9;20)(p13;q11.1),del(16)(q13),+21[19]/46,XX[1]
- DNA Index: 1
- Alternate Therapy: Surgery
- Cell of Origin: B-Precursor
